Gene-level copy-number profile of tumor specimen TCGA-R5-A805-01A from TCGA case TCGA-R5-A805, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.5 years (26,122 days).
Specimen TCGA-R5-A805-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.2d2f027c-c60e-4509-888e-4526a5f45b9e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R5-A805-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f0f14272-3c51-47f2-82d7-a700103da96b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 52; copy number 1: 16,623; copy number 2: 36,051; copy number 3: 5,906; copy number 4: 595; copy number 5: 241; copy number 6: 116; copy number 7: 114; copy number 8: 50; copy number 9: 21; copy number 10: 8; copy number 11: 33; copy number 18: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R5-A805-01A-11D-A363-01): tumor purity 0.44, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr4:142,286,917–142,518,983, 3 genes: RPL5P13, LSM3P4, AC139720.2.
- chr9:21,966,929–22,214,672, 9 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:75,592,644–75,628,120, 1 gene (within-gene range 0–5): AL589863.2.
- chr11:134,735,596–135,075,908, 6 genes (within-gene range 0–1): LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr16:78,534,374–78,553,296, 2 genes: AC046158.2, AC046158.3.
- chr18:36,297,714–36,780,055, 2 genes (within-gene range 0–1): FHOD3, AC055840.1.
- chr18:50,560,087–51,845,628, 20 genes: MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 586 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:122,607,864–125,143,528, 61 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:2,724,819–2,728,267, 1 gene, copy number 6: AL355361.1.
- chr10:3,009,976–3,066,001, 3 genes, copy number 5: AL731533.1, AL731533.3, AL731533.2.
- chr10:4,747,846–5,945,900, 42 genes, copy number 6–9 (within-gene range 4–9): AC018978.1, AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1, ANKRD16, RPL12P28, FBH1, AL137186.2.
- chr10:6,682,513–7,666,998, 16 genes, copy number 7 (within-gene range 4–7): AL158210.1, LINP1, AL392086.2, LINC00706, LINC00707, AL392086.1, AL392086.3, LINC02665, AL590095.1, SFMBT2, COX6CP17, AL139125.1, LINC02642, RNU6-535P, AL445070.1, ITIH5.
- chr10:9,721,963–10,366,487, 8 genes, copy number 10: HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1.
- chr10:11,611,305–12,043,170, 7 genes, copy number 6: AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P.
- chr10:73,995,193–74,150,842, 3 genes, copy number 9: VCL, AL596247.1, AP3M1.
- chr10:74,744,386–75,431,588, 24 genes, copy number 5: FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,552,553, 2 genes, copy number 5: AC010997.6, MIR606.
- chr10:77,587,049–79,067,895, 26 genes, copy number 7–8: RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1.
- chr10:79,347,469–79,827,602, 22 genes, copy number 6: PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B, AL135925.1.
- chr10:112,446,998–117,549,546, 82 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr10:122,271,296–123,171,875, 25 genes, copy number 7: BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, AL603764.1, AL603764.2, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A, C10orf88, PSTK, IKZF5, ACADSB, HMX3, HMX2, BUB3, RPS26P39.
- chr10:123,991,910–125,749,525, 33 genes, copy number 5–7 (within-gene range 2–7): YBX2P1, AL683842.1, CHST15, OAT, NKX1-2, AL445237.1, LHPP, RPS10P18, AC068896.1, FAM53B, AL513190.1, FAM53B-AS1, EEF1AKMT2, Y_RNA, ABRAXAS2, Y_RNA, NPM1P31, AL731577.2, ZRANB1, AL731577.1, CTBP2, AL731571.1, MIR4296, AL157888.1, MRPS21P6, RPS27P18, TEX36-AS1, TEX36, ALDOAP2, AL158835.1, EDRF1-DT, AL158835.3, AL158835.2.
- chr10:125,725,634–125,752,110, 1 gene, copy number 7 (within-gene range 2–7): EDRF1-AS1.
- chr15:83,962,176–85,749,358, 64 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:94,231,538–94,483,952, 1 gene, copy number 5 (within-gene range 2–5): MCTP2.
- chr15:94,455,469–95,507,865, 14 genes, copy number 5: AC009432.2, LINC02852, AC009432.1, AC022308.1, AC087633.2, AC107976.1, AC087633.1, AC087636.1, LINC01197, AC104260.1, AC104260.2, AC104260.3, LINC00924, AC027013.1.
- chr15:95,745,804–101,252,048, 120 genes, copy number 6–11 (within-gene range 1–11) (broad region; genes not listed).
- chr18:26,226,445–28,177,946, 31 genes, copy number 5–18 (within-gene range 1–18): TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1.

Autosomal genes at a single copy (total copy number 1): 14,209. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
